Gene-level copy-number profile of tumor specimen HTMCP-01-15-00366-01A from CGCI case HTMCP-01-15-00366, project CGCI-HTMCP-DLBCL (HIV+ Tumor Molecular Characterization Project - Diffuse Large B-Cell Lymphoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 46.8 years (17,110 days).
Specimen HTMCP-01-15-00366-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f904bbb1-6e89-4c8a-a080-3a323c10418d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-01-15-00366-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,246 have no estimate.
https://portal.gdc.cancer.gov/files/faab3b9c-c66c-4ec5-b448-365964b2755a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 51; copy number 1: 2,034; copy number 2: 48,317; copy number 3: 7,399; copy number 4: 501; copy number 5: 65; copy number 6: 5; copy number 8: 1; copy number 9: 2; copy number 11: 1; copy number 12: 1.

Homozygous deletions (total copy number 0; autosomes only): 51 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:5,478,736–5,494,674, 2 genes: Z98259.3, Z98259.1.
- chr1:160,537,073–160,711,831, 6 genes: AL138930.1, CD84, SLAMF1, SETP9, AL121985.1, CD48.
- chr1:196,819,731–196,959,622, 4 genes (within-gene range 0–2): CFHR1, BX248415.1, CFHR4, CFHR2.
- chr2:88,931,666–88,979,081, 4 genes (within-gene range 0–1): IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7.
- chr2:89,009,982–89,046,466, 5 genes (within-gene range 0–1): IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13.
- chr6:29,849,550–29,906,909, 6 genes (within-gene range 0–1): AL645929.2, HCP5B, AL645929.1, HLA-H, HLA-T, DDX39BP1.
- chr7:26,533,121–26,541,048, 2 genes: KIAA0087, AC004947.2.
- chr7:62,275,361–62,275,678, 1 gene: AC128676.1.
- chr7:73,005,541–73,111,140, 14 genes (within-gene range 0–2): PMS2P7, Y_RNA, SPDYE8, PMS2P8, Y_RNA, AC211476.5, AC211476.3, SPDYE11, AC211476.4, Y_RNA, SPDYE9, PMS2P6, Y_RNA, SPDYE10P.
- chr9:99,104,038–99,154,192, 2 genes: TGFBR1, RNA5SP290.
- chr10:129,837,505–129,845,895, 3 genes (within-gene range 0–1): AL354950.2, MIR4297, AL354950.1.
- chr11:69,083,176–69,109,094, 2 genes (within-gene range 0–1): MIR3164, AP003071.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 58 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:15,792,796–15,848,147, 4 genes, copy number 5 (within-gene range 2–5): RPL12P14, UQCRHL, AL450998.1, FLJ37453.
- chr1:155,687,960–155,859,400, 4 genes, copy number 5 (within-gene range 3–5): DAP3, AL162734.1, MSTO2P, GON4L.
- chr1:224,114,111–224,213,625, 5 genes, copy number 5: FBXO28, AC092809.3, DEGS1, SNORA72, AC092809.2.
- chr6:37,170,152–37,175,428, 1 gene, copy number 5: PIM1.
- chr7:74,082,933–74,122,525, 1 gene, copy number 6: LIMK1.
- chr7:74,289,407–74,405,935, 1 gene, copy number 5: CLIP2.
- chr7:102,681,836–102,690,469, 1 gene, copy number 12: RASA4DP.
- chr7:149,126,416–149,183,042, 1 gene, copy number 5: ZNF398.
- chr10:68,331,174–68,472,121, 5 genes, copy number 5 (within-gene range 2–5): HNRNPH3, RUFY2, DNA2, RPL26P29, RNA5SP319.
- chr11:48,880,111–48,908,946, 4 genes, copy number 6: AC027369.6, AC027369.3, AC027369.4, AC027369.5.
- chr12:110,372,900–110,450,422, 4 genes, copy number 5: ANAPC7, AC144548.1, HMGA1P3, ARPC3.
- chr16:28,659,696–28,817,828, 9 genes, copy number 5–11: AC145285.4, EIF3C, CDC37P1, MIR6862-2, AC145285.5, NPIPB9, AC145285.7, AC145285.2, AC145285.1.
- chr16:30,182,827–30,254,510, 11 genes, copy number 5: CORO1A, AC012645.3, BOLA2B, SLX1A, SLX1A-SULT1A3, SULT1A3, AC106782.1, AC106782.6, AC106782.3, AC106782.2, NPIPB13.
- chr17:67,774,591–67,785,293, 2 genes, copy number 5: RPSAP67, RPL17P41.
- chr19:48,793,152–48,868,617, 5 genes, copy number 5: RNU6-317P, BCAT2, AC026803.3, HSD17B14, PLEKHA4.

Autosomal genes at a single copy (total copy number 1): 2,034. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
